Gene-level copy-number profile of tumor specimen TCGA-AR-A0TW-01A from TCGA case TCGA-AR-A0TW, project TCGA-BRCA (Breast Invasive Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Breast, NOS; AJCC pathologic stage: Stage IIIA; Age at diagnosis: 50.0 years (18,263 days).
Specimen TCGA-AR-A0TW-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BRCA.18466ec8-1c12-4047-b792-9693e00fe15b.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-AR-A0TW-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 830 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/2979be15-da13-4adc-93f8-7f8fe2c1e7fb

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 14; copy number 1: 2,268; copy number 2: 11,769; copy number 3: 24,493; copy number 4: 12,523; copy number 5: 4,379; copy number 6: 2,619; copy number 7: 288; copy number 8: 858; copy number 9: 36; copy number 11: 117; copy number 12: 58; copy number 13: 113; copy number 14: 18; copy number 16: 125; copy number 17: 10; copy number 19: 73; copy number 21: 32.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-AR-A0TW-01A-11D-A087-01): tumor purity 0.48, ploidy 3.27, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 14 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:21,802,636–22,029,594, 2 genes (within-gene range 0–1): MTAP, AL359922.1.
- chr9:21,858,910–22,214,672, 12 genes: AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A, CDKN2B-AS1, AL449423.1, CDKN2B, UBA52P6, AL354709.1, AL354709.2, AL157937.1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 1,728 genes in 26 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:191,823,432–209,380,518, 361 genes, copy number 8 (within-gene range 4–8) (broad region; genes not listed).
- chr2:207,074,137–209,734,118, 57 genes, copy number 8 (within-gene range 3–8): KLF7, MIR2355, KLF7-IT1, MYOSLID, MIR7845, AC007879.1, AC007879.3, AC007879.5, AC007879.2, AC007879.4, AC009226.1, LINC01802, MIR1302-4, CREB1, METTL21A, RPS29P9, LINC01857, RNU6-664P, PPP1R14BP2, Y_RNA, CCNYL1, AC096772.1, MIR4775, FZD5, PLEKHM3, AC083900.1, RNU6-360P, RPL9P14, RNA5SP116, RPL12P17, CRYGEP, CRYGD, CRYGC, AC093698.1, CRYGB, CRYGA, C2orf80, RPSAP27, TPT1P2, IDH1, IDH1-AS1, PIKFYVE, MYL6BP1, PTH2R, ARPC1BP1, H3P9, AC019185.1, AC019185.2, AC109824.1, RNA5SP117, HSPA8P6, CRYGFP, MEAF6P1, PKP4P1, AC016743.1, MAP2, RNA5SP118.
- chr2:212,581,357–214,684,246, 18 genes, copy number 8 (within-gene range 3–8): AC093865.1, LINC01878, PCED1CP, AC108066.1, MIR4776-1, MIR4776-2, AC108066.2, IKZF2, AC079610.1, LINC01953, AC079610.2, SPAG16-DT, SPAG16, MIR4438, AC068051.1, RPL5P8, VWC2L, VWC2L-IT1.
- chr2:214,810,181–215,848,954, 17 genes, copy number 7 (within-gene range 3–7): SNHG31, SNORA70I, RPL10P6, ABCA12, AC072062.1, AC092844.1, LINC02862, ATIC, FN1, AC012462.3, AC012462.1, AC012462.2, AC012668.2, AC012668.3, AC012668.1, LINC00607, LINC01614.
- chr5:29,104,880–32,656,022, 55 genes, copy number 8: AC024589.1, AC024589.3, AC112172.2, LINC02064, AC027345.1, UBL5P1, AC108082.1, AC010374.2, AC010374.1, RN7SKP207, AC018765.1, HPRT1P2, AC114300.1, AC099517.1, AC026433.1, RPL19P11, AC026421.1, AC113386.1, CDH6, DUX4L51, DROSHA, Y_RNA, C5orf22, AC022417.1, RNU6-363P, PDZD2, AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6, RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279, AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579, AC074134.1, SUB1, LINC02061, AC008766.1.
- chr5:33,424,025–45,895,970, 205 genes, copy number 7–8 (broad region; genes not listed).
- chr5:172,641,263–172,691,540, 1 gene, copy number 8 (within-gene range 4–8): NEURL1B.
- chr5:172,662,165–173,451,591, 30 genes, copy number 8–12 (within-gene range 6–12): MIR5003, AC027309.1, AC022217.2, AC022217.1, AC022217.3, DUSP1, Y_RNA, AC022217.4, AC110011.1, ERGIC1, AC008429.1, AC008429.3, RPL26L1, AC008429.2, ATP6V0E1, AC008429.4, SNORA74B, Y_RNA, CREBRF, CDC42P5, AC008378.1, BNIP1, RPL7AP33, NKX2-5, Y_RNA, RNA5SP200, STC2, MIR8056, RNU6-500P, AC016573.1.
- chr5:180,293,245–180,295,253, 1 gene, copy number 7: AC008610.1.
- chr6:76,660,486–79,833,386, 29 genes, copy number 7–13: AL590426.1, AL355612.1, AL365222.1, HTR1B, RPS6P7, MEI4, AL121718.1, AL450327.1, IRAK1BP1, PHIP, AL356776.1, AL356776.2, HMGN3, HMGN3-AS1, AL355796.1, Y_RNA, LCAL1, AL355379.1, AL078601.1, AL078601.2, AL391840.1, DBIP1, LCA5, AL391840.3, AL391840.2, AL451064.1, AL451064.2, SH3BGRL2, LINC01621.
- chr6:89,568,144–91,690,428, 22 genes, copy number 8 (within-gene range 4–8): LYRM2, MDN1, AL096678.1, DNAJC19P6, PIMREGP3, CASP8AP2, Y_RNA, RPL22P14, AL353692.1, GJA10, Y_RNA, BACH2, AL121787.1, RN7SKP110, AL158136.1, AL117342.1, AL132996.1, MIR4464, MAP3K7, AL080284.1, MIR4643, CASC6.
- chr6:94,344,737–94,447,179, 4 genes, copy number 7: AL078595.1, AL078595.3, AL078595.2, MTCYBP36.
- chr6:95,577,535–100,881,372, 53 genes, copy number 7–17 (within-gene range 1–17): MANEA, AL607077.1, AL034348.1, KRT18P50, FUT9, UFL1-AS1, RN7SL797P, UFL1, FHL5, RPS7P8, RNU4-70P, TYMSP1, AL355143.1, EEF1GP6, AL033379.1, GPR63, NDUFAF4, RN7SL509P, KLHL32, MMS22L, AL589740.1, AL080316.1, MIR2113, EIF4EBP2P3, AL590727.1, AL589826.1, AL589826.2, POU3F2, FBXL4, AL078603.1, MIR548AI, BDH2P1, FAXC, COQ3, PNISR, AL513550.1, USP45, TSTD3, Y_RNA, CCNC, AL137784.1, PRDM13, Y_RNA, MCHR2, MCHR2-AS1, NPM1P38, AL080285.2, PRDX2P4, AL080285.1, SIM1, SIM1-AS1, ASCC3, Z86062.1.
- chr6:101,181,257–102,070,083, 1 gene, copy number 7 (within-gene range 1–7): GRIK2.
- chr6:102,078,872–107,700,218, 59 genes, copy number 7–21: AP002530.1, AL357139.2, AL357139.1, Z98755.1, AL591387.1, AL590608.1, R3HDM2P2, NPM1P10, AL357522.1, AL356967.1, HACE1, RNU6-897P, AL357315.1, AL357315.2, LIN28B-AS1, LIN28B, RNU6-1106P, BVES, BVES-AS1, POPDC3, PREP, AL133406.2, AL133406.1, RPL35P3, AL096794.1, LINC02836, Z97206.1, AL591518.1, RN7SKP211, PRDM1, ATG5, AL022067.1, U4, RN7SL47P, RNU6-344P, AL356859.1, CRYBG1, Y_RNA, RNA5SP211, AL109920.1, Y_RNA, RTN4IP1, RNU6-527P, QRSL1, RPL21P65, LINC02526, LINC02532, RNU6-117P, MIR587, CD24, MTRES1, BEND3, RNU6-1299P, PDSS2, AL591516.1, RPS24P12, SOBP, AL121957.1, AL096816.1.
- chr6:133,240,598–133,892,802, 8 genes, copy number 8 (within-gene range 1–8): EYA4, AL024497.1, AL024497.2, TARID, HSPE1P21, AL450270.1, FTH1P26, LINC01312.
- chr6:136,557,046–142,446,266, 80 genes, copy number 7–19 (within-gene range 3–19) (broad region; genes not listed).
- chr7:3,301,252–4,269,000, 1 gene, copy number 7 (within-gene range 5–7): SDK1.
- chr7:4,130,181–4,134,837, 1 gene, copy number 7: AC017000.1.
- chr12:70,468,080–71,800,286, 21 genes, copy number 9 (within-gene range 5–9): AC025569.1, PTPRB, AC083809.1, PTPRR, FAHD2P1, Y_RNA, AC123905.1, AC025575.1, AC025575.2, TSPAN8, LGR5, AC090116.1, AC078860.3, AC078860.2, ZFC3H1, AC078860.1, THAP2, AC073612.1, TMEM19, AC011601.1, RAB21.
- chr17:49,457,861–74,623,738, 616 genes, copy number 7–19 (broad region; genes not listed).
- chr18:79,069,285–80,097,088, 33 genes, copy number 7 (within-gene range 2–7): ATP9B, AC099689.3, AC125437.1, AC125437.2, AC125437.3, AC104423.1, AC023090.1, AC023090.2, NFATC1, AC018445.3, AC018445.5, AC018445.1, AC018445.4, AC018445.2, AC018445.6, AC068473.3, AC068473.4, AC068473.1, AC068473.5, CTDP1, AC068473.2, AC021594.1, AC021594.2, KCNG2, AC114341.1, SLC66A2, AC114341.2, HSBP1L1, TXNL4A, AC090360.1, RBFA, RBFADN, SLC25A6P4.
- chr20:48,624,252–49,892,242, 27 genes, copy number 7–11 (within-gene range 5–11): PREX1, AL035106.1, AL133342.1, ARFGEF2, SNAP23P1, CSE1L-AS1, CSE1L, STAU1, ARPC3P1, DDX27, ZNFX1, ZFAS1, AL049766.2, SNORD12C, AL049766.1, SNORD12B, AL049766.3, SNORD12, KCNB1, AL035685.1, PTGIS, B4GALT5, RN7SL197P, SNRPFP1, RNU6-919P, SLC9A8, AL162615.1.
- chr20:53,255,979–53,875,557, 12 genes, copy number 9 (within-gene range 6–9): AL109930.1, AL354993.1, PPIAP10, AL354993.2, Y_RNA, AL157838.1, ZNF217, AC005808.1, RNU7-14P, AC005914.1, AC006076.1, SUMO1P1.
- chr20:53,940,160–53,942,508, 1 gene, copy number 9: AC005220.1.
- chr20:57,105,741–57,393,062, 15 genes, copy number 8: AL157414.2, AL157414.1, AL157414.4, AL157414.3, BMP7, BMP7-AS1, AL122058.1, Y_RNA, MIR4325, RPL39P39, SPO11, RAE1, MTND1P9, MTRNR2L3, RBM38-AS1.

Autosomal genes at a single copy (total copy number 1): 2,259. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
